FM case AD11390 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms.
https://portal.gdc.cancer.gov/cases/3e797b39-831b-4364-a2cf-d2a61620df7b

Male, 54.9 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3); specimen biopsied or resected from the parotid gland. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
